Somatic mutation profile of tumor specimen 0DUKHA from CCDI case PBCLIU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 15.5 years (5,651 days).
Specimen 0DUKHA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e62aa806-df1b-44ac-b81d-2f33e0eea31b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58d6d46e-1992-423f-8d65-cc2ad5f31d99

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, Silent 3, 3'UTR 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTK2B | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 168/786 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57766735; called by muse, mutect2, varscan2
- SLC26A7 | c.1898C>A p.S633* | Nonsense Mutation (SNP) | VAF 851/1793 reads (47%) | catalogued as COSV52593987; called by muse, mutect2, varscan2
- BCAS4 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 250/1187 reads (21%) | called by muse, mutect2, varscan2
- COL26A1 | c.1030-5C>T | Splice Region (SNP) | VAF 66/271 reads (24%) | called by mutect2, varscan2
- DHRS12 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 259/729 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PLXND1 | c.3662G>T p.S1221I | Missense Mutation (SNP) | VAF 134/446 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SNTB1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 573/1321 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- NDUFA11 | c.93C>T p.V31= | Silent (SNP) | VAF 50/2061 reads (2%) | catalogued as rs1235174774; called by muse, mutect2
- PANX2 | c.588C>T p.I196= | Silent (SNP) | VAF 334/1064 reads (31%) | catalogued as COSV50312160; called by muse, mutect2, varscan2
- RTL8A | c.96G>A p.T32= | Silent (SNP) | VAF 335/2458 reads (14%) | catalogued as rs1203551385; called by muse, mutect2, varscan2
- COL6A2 | c.735+83G>A | Intron (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- FAM110B | c.*9G>A | 3'UTR (SNP) | VAF 126/514 reads (25%) | catalogued as rs1222541886, COSV100825994; called by muse, mutect2, varscan2
- IGFN1 | c.1241+1804G>A | Intron (SNP) | VAF 40/424 reads (9%) | catalogued as rs557096408; called by muse, mutect2
- PIK3C2B | c.1748-100A>G | Intron (SNP) | VAF 20/62 reads (32%) | called by mutect2, varscan2
- RPL30 | c.*42G>C | 3'UTR (SNP) | VAF 472/963 reads (49%) | called by muse, mutect2, varscan2
